CCDI case PBCACU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/6f0d8dd7-a145-4ea1-abc7-5b64da5b6b8c

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 9.3 years (3,412 days).

Biospecimens (3 samples)
- Sample 0DMKB1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMKB6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DMKD4: Tissue type: Tumor; Specimen type: Solid Tissue.
